CCDI case PBBXDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4bb5bc5c-ff6e-412a-bc98-0b25173a2611

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,128 days).

Biospecimens (3 samples)
- Sample 0DJTFO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJTFW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJTG2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
